Somatic mutation profile of tumor specimen TCGA-85-6560-01A (aliquot TCGA-85-6560-01A-11D-1817-08) from TCGA case TCGA-85-6560, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.6 years (21,768 days).
Specimen TCGA-85-6560-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 419cdf90-22af-4ccd-86ad-fcd35763fed5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-6560-10A (Blood Derived Normal), aliquot TCGA-85-6560-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f560a3a4-0593-48cd-bda1-e85d3e862c31

The open-access MAF lists 445 somatic variants for this specimen: 356 protein-altering or splice-affecting, 77 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 308, Silent 77, Nonsense Mutation 20, Frame Shift Del 11, Intron 9, Splice Site 7, Frame Shift Ins 6, 5'UTR 2, Splice Region 1, Translation Start Site 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MMUT | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs780387525, CM050678, COSV51272444; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.405C>G p.C135W | Missense Mutation (SNP) | VAF 16/41 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519976, COSV52665429, COSV52669330, COSV52682693, COSV52815283; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AAGAB | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 78/298 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs779782680, COSV56016015; called by muse, mutect2, varscan2
- ABCA13 | c.5047G>T p.E1683* | Nonsense Mutation (SNP) | VAF 30/150 reads (20%) | catalogued as COSV70026204; called by muse, mutect2, varscan2
- AC068580.4 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 105/234 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as rs375052866; called by muse, mutect2, varscan2
- ACACB | c.6943-2A>G p.X2315_splice | Splice Site (SNP) | VAF 34/75 reads (45%) | catalogued as COSV58129575; called by muse, mutect2, varscan2
- ACKR2 | c.399T>A p.F133L | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV56177024; called by muse, mutect2, varscan2
- ADAM20 | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV56454249; called by muse, mutect2, varscan2
- ADAM20 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1369566159, COSV56454255; called by muse, mutect2, varscan2
- ADAM23 | c.788A>T p.N263I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV52209116; called by muse, mutect2, varscan2
- ADAMTS19 | c.1109A>G p.K370R | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs768193614, COSV50733768; called by muse, mutect2, varscan2
- ADAMTS9 | c.4004G>C p.G1335A | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55776219; called by muse, mutect2, varscan2
- ADAMTSL1 | c.71G>T p.R24M | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52809659; called by muse, mutect2, varscan2
- ADGRB3 | c.1031-1G>C p.X344_splice | Splice Site (SNP) | VAF 22/118 reads (19%) | catalogued as COSV65385230, COSV65411274; called by muse, mutect2, varscan2
- ADGRF4 | c.1377A>G p.I459M | Missense Mutation (SNP) | VAF 9/273 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1382833471, COSV51950118; called by muse, mutect2
- ADGRV1 | c.9707G>A p.S3236N | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV67979646; called by muse, mutect2, varscan2
- AFF2 | c.690C>G p.F230L | Missense Mutation (SNP) | VAF 123/192 reads (64%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.468); catalogued as COSV60656756; called by muse, mutect2, varscan2
- AGBL1 | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.287); catalogued as COSV66850624; called by muse, mutect2, varscan2
- AGBL1 | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.047); catalogued as COSV66850629; called by muse, mutect2, varscan2
- AGBL1 | c.1505A>C p.H502P | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV66850636; called by muse, mutect2, varscan2
- AGMAT | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as rs553000649, COSV65435652; called by mutect2, varscan2
- AHNAK | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs186340112, COSV57205603; called by muse, mutect2, varscan2
- AKAP11 | c.4221G>T p.K1407N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV50293216; called by muse, mutect2, varscan2
- AKAP11 | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV50293233; called by muse, mutect2, varscan2
- ALPL | c.1484G>A p.G495D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100876300, COSV66375972; called by muse, mutect2, varscan2
- ANO3 | c.2188C>A p.H730N | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56782720; called by muse, mutect2, varscan2
- ANPEP | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.673); catalogued as COSV55589686, COSV55591678; called by muse, mutect2, varscan2
- APBA1 | c.797A>T p.Q266L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs1475551388, COSV55222683; called by muse, varscan2
- APC | c.2752G>T p.E918* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as CM040978, COSV57328628, COSV57339762, COSV99965505; called by muse, mutect2, varscan2
- APC | c.5766G>T p.Q1922H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV57328643; called by muse, mutect2, varscan2
- ARHGEF37 | c.1334A>C p.Q445P | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV61368074; called by muse, mutect2, varscan2
- ARPP21 | c.936T>A p.S312R | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV51793137; called by muse, mutect2, varscan2
- ASB17 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV52409524; called by muse, mutect2, varscan2
- ASB7 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1177867687, COSV58403355; called by muse, mutect2, varscan2
- ASMTL | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV67243037; called by muse, mutect2, varscan2
- ASPM | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as COSV54125778; called by muse, mutect2, varscan2
- ASTN2 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV100529649, COSV57755805; called by muse, mutect2, varscan2
- ATP4A | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as COSV52866125; called by muse, mutect2, varscan2
- ATP9A | c.279T>A p.F93L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV58763897; called by muse, mutect2, varscan2
- BCAR3 | c.1879C>G p.L627V | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53072670; called by muse, mutect2, varscan2
- BCHE | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV52254144; called by muse, mutect2, varscan2
- BRD1 | c.2109G>T p.L703F | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV53455204; called by muse, mutect2, varscan2
- BRINP2 | c.2012C>A p.P671H | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs1012208156, COSV100838226, COSV64175956; called by muse, mutect2, varscan2
- C12orf50 | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.355); catalogued as COSV53893772; called by muse, mutect2, varscan2
- C1orf87 | c.8C>G p.S3* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as COSV100967118, COSV64596259; called by muse, mutect2, varscan2
- C2CD3 | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs141826355, COSV58090235; called by muse, mutect2, varscan2
- CACNA1G | c.5192C>T p.A1731V | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs369515451; called by muse, mutect2
- CAD | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53024252; called by muse, mutect2, varscan2
- CAPN11 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751623924, COSV67236372; called by muse, mutect2, varscan2
- CARMIL2 | c.2335G>T p.A779S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as COSV58023702; called by muse, mutect2, varscan2
- CD1A | c.659A>G p.Q220R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV56860545; called by muse, mutect2, varscan2
- CD44 | c.1381A>G p.M461V | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1292156322, COSV53528375; called by muse, mutect2, varscan2
- CDH22 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64836638; called by muse, mutect2, varscan2
- CEBPZ | c.631A>T p.K211* | Nonsense Mutation (SNP) | VAF 62/164 reads (38%) | catalogued as COSV50016984; called by muse, mutect2, varscan2
- CELSR1 | c.3980C>T p.S1327F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV53084742; called by muse, mutect2, varscan2
- CELSR2 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.401); catalogued as COSV54767842; called by muse, mutect2, varscan2
- CEP162 | c.721G>T p.V241L | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV57617924; called by muse, mutect2, varscan2
- CFAP61 | c.2464G>T p.A822S | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV55621147; called by muse, mutect2, varscan2
- CFAP74 | c.4709A>G p.E1570G | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs779724860, COSV60586321; called by muse, mutect2, varscan2
- CFAP91 | c.1630A>C p.K544Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56339563; called by muse, mutect2, varscan2
- CHAT | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.102); catalogued as COSV60320973; called by muse, varscan2
- CHRNB2 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773957177, COSV63807807; called by muse, mutect2
- CHST2 | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.321); catalogued as COSV58884832; called by muse, mutect2, varscan2
- CLASP2 | c.2891A>G p.K964R (on ENST00000359576; = p.K963R on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/226 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as COSV56277214; called by muse, mutect2, varscan2
- CLCA1 | c.2456C>T p.A819V | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV52325608; called by muse, mutect2, varscan2
- CNBP | c.125-2A>G p.X42_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | catalogued as COSV69654383; called by muse, mutect2, varscan2
- CNKSR2 | c.1718G>C p.C573S | Missense Mutation (SNP) | VAF 73/136 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV54250487; called by muse, mutect2, varscan2
- COL11A1 | c.521A>T p.K174I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV62174885; called by muse, mutect2, varscan2
- COL12A1 | c.1170T>A p.S390R | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV59390871; called by muse, mutect2, varscan2
- COX19 | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 89/392 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV59937325; called by muse, mutect2, varscan2
- CPS1 | c.1311G>T p.Q437H | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51803695; called by muse, mutect2, varscan2
- CPZ | c.1726C>T p.R576C (on ENST00000360986 / NM_001014447.3; = p.R565C on NM_003652.3) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147183461, COSV59921853; called by muse, mutect2, varscan2
- CSNK1A1L | c.516C>A p.H172Q | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65789406; called by muse, mutect2, varscan2
- CTIF | c.685G>T p.G229W | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56480568; called by muse, mutect2, varscan2
- CWF19L2 | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV56509725; called by muse, mutect2, varscan2
- DAB2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs775097329, COSV57912746; called by muse, mutect2, varscan2
- DCAF8L1 | c.358T>A p.C120S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV71595156; called by muse, mutect2, varscan2
- DIDO1 | c.2104A>G p.I702V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV56615423; called by muse, mutect2, varscan2
- DNAH17 | c.2622T>G p.F874L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV101101368; called by muse, mutect2, varscan2
- DNAH9 | c.8991G>C p.L2997F | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV52337604; called by muse, mutect2, varscan2
- DNAJC6 | c.1258T>C p.Y420H | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV54770703; called by muse, mutect2, varscan2
- DOCK11 | c.5216A>G p.Y1739C | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52234733; called by muse, mutect2, varscan2
- DOK3 | c.860T>G p.M287R | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as COSV57251181; called by muse, mutect2, varscan2
- DPP6 | c.914G>T p.W305L (on ENST00000377770 / NM_001364500.2; = p.W243L on NM_001936.5) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV59600743; called by muse, mutect2, varscan2
- DSCAML1 | c.2335C>A p.P779T (on ENST00000321322; = p.P719T on NM_020693.4) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58383461; called by muse, mutect2, varscan2
- EARS2 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs558487697, COSV71942764; called by muse, mutect2, varscan2
- EBF1 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV58169378; called by muse, mutect2
- ECHDC2 | c.676G>T p.A226S (on ENST00000371522 / NM_001198961.2; = p.A195S on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV64300169; called by muse, mutect2, varscan2
- ECT2L | c.2025G>T p.E675D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62883025; called by muse, mutect2, varscan2
- EIF2AK1 | c.411+2T>A p.X137_splice | Splice Site (SNP) | VAF 17/90 reads (19%) | catalogued as COSV52236682; called by muse, mutect2, varscan2
- ELL2 | c.1837A>T p.R613* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV52981401; called by muse, mutect2, varscan2
- ENAM | c.2390C>A p.P797Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV68535374; called by muse, mutect2, varscan2
- ENPP1 | c.302G>T p.C101F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as COSV62930556; called by muse, mutect2, varscan2
- ENPP1 | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV62930565; called by muse, mutect2, varscan2
- ENPP6 | c.746T>C p.M249T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1426333714, COSV57066344; called by muse, mutect2, varscan2
- EPB41L4A | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV54863770, COSV54866694; called by muse, mutect2, varscan2
- EPHA3 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1559743082, COSV60696168; called by muse, mutect2, varscan2
- EPOR | c.847T>A p.W283R | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55799789; called by muse, mutect2, varscan2
- EPPK1 | c.4282G>T p.G1428* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV101599729; called by muse, mutect2, varscan2
- EPS8L1 | c.74A>G p.Y25C | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52380277; called by muse, mutect2, varscan2
- EPX | c.1923C>G p.F641L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56595284; called by muse, mutect2, varscan2
- EPYC | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as COSV53798694; called by muse, mutect2, varscan2
- ERF | c.1624T>G p.S542A | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); catalogued as COSV55895143; called by muse, mutect2, varscan2
- ERI3 | c.933C>T p.D311= | Splice Region (SNP) | VAF 15/68 reads (22%) | catalogued as rs773605425, COSV59999922; called by muse, mutect2, varscan2
- ERICH1 | c.1303C>A p.H435N | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.669); catalogued as COSV50637339; called by muse, mutect2, varscan2
- F10 | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as COSV65020905, COSV65023449; called by muse, mutect2, varscan2
- F3 | c.522C>G p.S174R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as rs200192517; called by muse, mutect2, varscan2
- FAM135B | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV52709212, COSV99429035; called by muse, mutect2, varscan2
- FAM163A | c.124G>T p.V42F | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV59202552; called by muse, mutect2, varscan2
- FAM237A | c.117G>T p.L39F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs775042467, COSV101405583, COSV69304927; called by muse, mutect2, varscan2
- FCGR3B | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs201534974, COSV54209122; called by muse, mutect2, varscan2
- FMO2 | c.655T>A p.W219R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52946957; called by muse, mutect2, varscan2
- GALNT13 | c.542G>T p.R181M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67211731; called by muse, mutect2, varscan2
- GIMAP5 | c.796A>T p.N266Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV57529694; called by muse, mutect2, varscan2
- GLMN | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs773446747, COSV104427705, COSV64859963; called by muse, varscan2
- GOLGB1 | c.272A>C p.N91T | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61462415; called by muse, mutect2, varscan2
- GPR183 | c.275C>A p.A92E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV63117182; called by muse, mutect2, varscan2
- GPR183 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.785); catalogued as COSV63117184; called by muse, mutect2, varscan2
- GPT | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777370445, COSV52952376; called by muse, mutect2, varscan2
- GRAMD1C | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1433240153, COSV63982017, COSV63984161; called by muse, mutect2
- GRIA3 | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 100/148 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV52050902; called by muse, mutect2, varscan2
- GRIK3 | c.2488G>T p.A830S | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as rs753008196, COSV66136278; called by muse, mutect2, varscan2
- GRIN3A | c.2341C>T p.H781Y | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV62451458; called by muse, mutect2, varscan2
- GRM1 | c.2396T>A p.L799Q | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51112009; called by muse, mutect2, varscan2
- GTF2H1 | c.677A>G p.Q226R | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56377253; called by muse, mutect2, varscan2
- GTF3C2 | c.1053G>T p.Q351H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV53125306; called by muse, mutect2, varscan2
- GUCY1B1 | c.1159A>C p.K387Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV52374001; called by muse, mutect2, varscan2
- H2AC6 | c.368G>C p.S123T | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs770890655, COSV58415075; called by muse, mutect2, varscan2
- HAPLN4 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs754562605, COSV52268637; called by muse, mutect2, varscan2
- HAUS6 | c.551A>C p.D184A | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV63252849; called by muse, mutect2, varscan2
- HCN1 | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.334); catalogued as rs1221257807, COSV57496411, COSV57526158; called by muse, mutect2, varscan2
- HEATR5B | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs780946610, COSV51849757; called by muse, mutect2, varscan2
- HECW1 | c.2806G>A p.G936R | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV67823509; called by muse, mutect2, varscan2
- HECW1 | c.3862G>T p.E1288* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV67823517; called by muse, mutect2, varscan2
- HHIP | c.137A>G p.K46R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56837061; called by muse, mutect2, varscan2
- HMCN1 | c.14338C>T p.R4780W | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353587559, COSV54881655; called by muse, mutect2, varscan2
- HMGB4 | c.353G>C p.W118S | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1374719674, COSV53880525, COSV53885718; called by muse, mutect2, varscan2
- HOMER3 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 40/86 reads (47%) | catalogued as COSV55354984, COSV55357242; called by muse, mutect2, varscan2
- HRNR | c.1908C>G p.H636Q | Missense Mutation (SNP) | VAF 60/367 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV64255104; called by muse, mutect2, varscan2
- HSD11B1 | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54826172; called by muse, mutect2, varscan2
- HTR1E | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59506972; called by muse, mutect2, varscan2
- HTR1F | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV60389120, COSV60390188; called by muse, mutect2, varscan2
- IGSF9 | c.1742A>G p.Q581R (on ENST00000368094 / NM_001135050.2; = p.Q565R on NM_020789.4) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63639123; called by muse, mutect2, varscan2
- IKZF4 | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.145); catalogued as COSV56267038; called by muse, mutect2, varscan2
- IL18R1 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52122913, COSV52126993; called by muse, mutect2, varscan2
- IL23R | c.1271G>A p.S424N | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV61373115; called by muse, mutect2
- IPO13 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV64893894; called by muse, mutect2, varscan2
- IQSEC1 | c.2324A>G p.Q775R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56221649; called by muse, mutect2, varscan2
- IRF4 | c.713G>T p.S238I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV66704553; called by muse, mutect2, varscan2
- ITGBL1 | c.919G>T p.G307W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763196114, COSV66005867; called by muse, mutect2, varscan2
- KCNG1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as rs1187419187, COSV65368174; called by muse, mutect2, varscan2
- KCNQ2 | c.2028C>A p.S676R (on ENST00000359125 / NM_172107.4; = p.S648R on NM_004518.6) | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV60541083; called by muse, mutect2, varscan2
- KCNQ5 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs771827882, COSV59651595; called by muse, mutect2, varscan2
- KDM6B | c.1196G>C p.S399T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); catalogued as rs765171715, COSV54678370; called by muse, mutect2, varscan2
- KDR | c.1297del p.D433Ifs*11 | Frame Shift Del (DEL) | VAF 45/111 reads (41%) | catalogued as COSV55772825, COSV55779397; called by mutect2, pindel, varscan2
- KIDINS220 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 94/365 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56750945; called by muse, mutect2, varscan2
- KIF17 | c.1565C>A p.A522E | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56116235, COSV99929073; called by muse, mutect2, varscan2
- KIF5A | c.2395A>G p.K799E | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54052119; called by muse, mutect2, varscan2
- KIFAP3 | c.2155G>C p.D719H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV63031440; called by muse, mutect2, varscan2
- KLB | c.1037A>T p.K346M | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); catalogued as COSV57300362; called by muse, mutect2, varscan2
- KLHL1 | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64767890; called by muse, mutect2, varscan2
- KLHL14 | c.1885T>G p.*629Eext*7 | Nonstop Mutation (SNP) | VAF 109/228 reads (48%) | catalogued as COSV63831042; called by muse, mutect2, varscan2
- KRTAP10-1 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV59953972; called by muse, mutect2, varscan2
- KRTAP5-5 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 76/173 reads (44%) | PolyPhen benign (0); catalogued as COSV68784424; called by muse, varscan2
- L1TD1 | c.1291G>T p.G431W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV100776531; called by muse, mutect2, varscan2
- L1TD1 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV63133194, COSV63133385; called by muse, mutect2, varscan2
- LAMB3 | c.2465T>A p.L822H | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV61915577; called by muse, mutect2, varscan2
- LARP1 | c.451G>A p.A151T (on ENST00000518297 / NM_033551.3; = p.A74T on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.056); catalogued as COSV60425226; called by muse, mutect2, varscan2
- LCE2D | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.746); catalogued as COSV64228851; called by muse, mutect2, varscan2
- LCT | c.5089A>G p.I1697V | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1213434353, COSV51544959; called by muse, mutect2, varscan2
- LEFTY2 | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV64746467; called by muse, mutect2, varscan2
- LHCGR | c.1016A>T p.K339M | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV54293465, COSV99683854; called by muse, mutect2, varscan2
- LIG4 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63596547; called by muse, mutect2, varscan2
- LIPA | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51078078; called by muse, mutect2, varscan2
- LPIN2 | c.2404A>G p.K802E | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV55237800; called by muse, mutect2, varscan2
- LRRC32 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); catalogued as COSV52631823; called by muse, mutect2, varscan2
- LRRC49 | c.922-2A>T p.X308_splice | Splice Site (SNP) | VAF 47/91 reads (52%) | catalogued as COSV53008486; called by muse, mutect2, varscan2
- LRRC7 | c.1073A>T p.Y358F (on ENST00000651989 / NM_001370785.2; = p.Y325F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV50417168; called by muse, mutect2, varscan2
- LRRIQ3 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs756201576, COSV63041638; called by muse, mutect2, varscan2
- LY9 | c.788A>G p.E263G | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV54431995; called by muse, mutect2, varscan2
- MAML2 | c.2782G>T p.G928* | Nonsense Mutation (SNP) | VAF 49/167 reads (29%) | catalogued as COSV73262875; called by muse, mutect2, varscan2
- MDGA2 | c.1004C>T p.T335I (on ENST00000399232 / NM_001113498.2; = p.T37I on NM_182830.4) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as COSV62080911, COSV62096085; called by muse, mutect2, varscan2
- MED25 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV57203204; called by muse, mutect2, varscan2
- METTL3 | c.62G>T p.R21M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53913745; called by muse, mutect2, varscan2
- MOB3B | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV51775878; called by muse, mutect2, varscan2
- MORC1 | c.1295A>C p.Q432P | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as rs767474103, COSV51714044; called by muse, mutect2, varscan2
- MPND | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV53656135; called by muse, mutect2, varscan2
- MS4A6A | c.324G>T p.R108S | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV60617191; called by muse, mutect2
- MUC17 | c.3671T>C p.M1224T | Missense Mutation (SNP) | VAF 94/490 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV60281726; called by muse, mutect2, varscan2
- MUC5B | c.5722A>G p.T1908A | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV71590397; called by muse, mutect2, varscan2
- MYCN | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV55257767, COSV55257941; called by muse, mutect2, varscan2
- MYLK4 | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 38/428 reads (9%) | catalogued as COSV51138829; called by muse, mutect2
- NCAPD3 | c.2082G>T p.K694N | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV73257934, COSV99074604; called by muse, mutect2, varscan2
- NFATC3 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1403954925, COSV60470514, COSV60471509; called by muse, mutect2, varscan2
- NKD2 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.756); catalogued as rs1027634939, COSV56890085; called by muse, mutect2, varscan2
- NLRC3 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.383); catalogued as COSV57087986; called by muse, varscan2
- NLRP13 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.397); catalogued as COSV61620373; called by muse, mutect2, varscan2
- NRSN1 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.721); catalogued as COSV65893730; called by muse, mutect2, varscan2
- NSD3 | c.2660A>G p.Y887C | Missense Mutation (SNP) | VAF 261/314 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as rs765531670, COSV57667398; called by muse, mutect2, varscan2
- NUP210L | c.3212A>C p.K1071T | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55142812; called by muse, mutect2, varscan2
- NYNRIN | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV66841372; called by muse, mutect2, varscan2
- ODF1 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 18/163 reads (11%) | catalogued as COSV53431781; called by muse, mutect2, varscan2
- OGFOD3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs756501679, COSV57339492; called by muse, mutect2, varscan2
- OR10S1 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1293990518, COSV73342687; called by muse, mutect2, varscan2
- OR11L1 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63313792; called by muse, mutect2, varscan2
- OR2A12 | c.611T>A p.F204Y | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV68821093; called by muse, mutect2, varscan2
- OR2AK2 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63549049; called by muse, mutect2, varscan2
- OR2J2 | c.427C>A p.H143N | Missense Mutation (SNP) | VAF 171/546 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.127); catalogued as COSV65847777; called by muse, varscan2
- OR2T33 | c.821C>A p.A274D | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV58814403, COSV58817745; called by muse, mutect2, varscan2
- OR51Q1 | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV56178042; called by muse, mutect2, varscan2
- OR52I1 | c.422C>G p.T141R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV56167748; called by muse, mutect2, varscan2
- OR5D14 | c.658T>G p.Y220D | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59455620; called by muse, mutect2, varscan2
- OR5L2 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65723496, COSV65724199; called by muse, mutect2, varscan2
- OR5L2 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV65723501, COSV65725092; called by muse, mutect2, varscan2
- OR6Q1 | c.788A>T p.Y263F | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758049819, COSV56932368; called by muse, mutect2, varscan2
- OR6Y1 | c.149T>A p.I50N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV56928412, COSV56929964; called by muse, mutect2, varscan2
- OR8B12 | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV60911057; called by muse, mutect2, varscan2
- OSBPL6 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51912226; called by muse, mutect2, varscan2
- PAPOLB | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV68199585; called by muse, mutect2, varscan2
- PARD3 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV61049676; called by muse, mutect2
- PATJ | c.4018C>G p.P1340A | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV56247659; called by muse, mutect2, varscan2
- PCDH11X | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV53447278; called by muse, mutect2, varscan2
- PCDHA2 | c.1600del p.Q534Rfs*2 | Frame Shift Del (DEL) | VAF 41/89 reads (46%) | catalogued as rs1355816339; called by mutect2, varscan2
- PDZRN4 | c.1987G>C p.E663Q (on ENST00000402685 / NM_001164595.2; = p.E405Q on NM_013377.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.28); catalogued as COSV54193916, COSV54215210; called by muse, mutect2, varscan2
- PEX7 | c.828C>G p.D276E | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV59248132; called by muse, mutect2, varscan2
- PGM2 | c.155G>C p.G52A | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV67938464; called by muse, mutect2, varscan2
- PHF21A | c.1205G>A p.G402E (on ENST00000418153 / NM_001101802.3; = p.G403E on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57650329; called by muse, mutect2, varscan2
- PIK3C2B | c.683A>T p.Y228F | Missense Mutation (SNP) | VAF 233/568 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV100915081, COSV65803427; called by muse, mutect2, varscan2
- PIK3CA | c.1641G>C p.E547D | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as COSV55888836, COSV55939262; called by muse, mutect2, varscan2
- PIP5K1A | c.1441A>G p.I481V (on ENST00000368888 / NM_001135638.2; = p.I468V on NM_003557.3) | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1193905962, COSV62957546; called by muse, mutect2, varscan2
- PKDCC | c.1244G>T p.S415I | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV54306025; called by muse, mutect2, varscan2
- PLA2G6 | c.1749G>C p.M583I | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.247); catalogued as COSV59268267; called by muse, mutect2, varscan2
- PNLIP | c.640A>T p.K214* | Nonsense Mutation (SNP) | VAF 29/52 reads (56%) | catalogued as COSV65039831; called by muse, mutect2, varscan2
- POLQ | c.1915A>C p.M639L | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV51747113, COSV51760031; called by muse, mutect2, varscan2
- POP1 | c.2122T>A p.W708R | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62892032; called by muse, mutect2, varscan2
- PROK1 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.924); catalogued as COSV54764420; called by muse, mutect2, varscan2
- PRSS23 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54706374; called by muse, mutect2, varscan2
- PRXL2B | c.603A>C p.K201N (on ENST00000444521; = p.K153N on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV56519050; called by muse, mutect2, varscan2
- PSD2 | c.250G>T p.G84W | Missense Mutation (SNP) | VAF 81/131 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as COSV51197334; called by muse, mutect2, varscan2
- PSMB4 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51850587; called by muse, mutect2, varscan2
- PSMD4 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV64393111; called by muse, mutect2, varscan2
- PTCH2 | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs758477982, COSV64710090; ClinVar: uncertain significance; called by mutect2, varscan2
- PTCHD4 | c.1144A>G p.I382V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1369461795, COSV59779202; called by muse, mutect2, varscan2
- PTGFR | c.758C>A p.A253E | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs145816454, COSV66114518; called by muse, mutect2, varscan2
- RAI14 | c.782A>T p.K261I | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV54290330; called by muse, mutect2, varscan2
- RASA3 | c.2177G>A p.G726E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV61864435; called by muse, mutect2, varscan2
- RASGRP4 | c.8G>T p.R3I | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53094259, COSV53098162; called by muse, mutect2, varscan2
- RAX | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV56874078; called by muse, mutect2, varscan2
- REG1B | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs754704891, COSV59304695; called by muse, mutect2, varscan2
- RIMS1 | c.4539C>G p.D1513E | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV53442316; called by muse, mutect2, varscan2
- RNF31 | c.2671A>T p.T891S | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV60725836; called by muse, mutect2, varscan2
- ROBO4 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs770826297, COSV60621888; called by muse, mutect2, varscan2
- RPE65 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs61752874, CM005351, COSV52013737; ClinVar: not provided; called by muse, mutect2, varscan2
- RPGR | c.819G>T p.Q273H | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390141758, COSV58832930; called by muse, mutect2, varscan2
- RYR2 | c.13165G>C p.G4389R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63667203; called by mutect2, varscan2
- SELE | c.1548C>A p.C516* | Nonsense Mutation (SNP) | VAF 38/90 reads (42%) | catalogued as COSV60974220; called by muse, mutect2, varscan2
- SEPTIN2 | c.979G>C p.A327P | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV63632090; called by muse, mutect2, varscan2
- SERINC2 | c.1204G>T p.V402F (on ENST00000373709 / NM_178865.5; = p.V406F on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs377048384, COSV65491037; called by muse, mutect2, varscan2
- SERP1 | c.39G>T p.K13N | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV53525672; called by muse, mutect2, varscan2
- SETBP1 | c.1405A>G p.K469E | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56314597; called by muse, mutect2, varscan2
- SETBP1 | c.2327T>A p.M776K | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV56314606; called by muse, mutect2, varscan2
- SGF29 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as rs1324158167, COSV100187093, COSV57681012; called by muse, mutect2, varscan2
- SI | c.1752C>G p.F584L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as COSV52268321; called by muse, mutect2
- SLC20A1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 70/341 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.896); catalogued as rs1451742197, COSV55610399; called by muse, mutect2, varscan2
- SLC25A25 | c.109A>C p.S37R | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV66085793; called by muse, mutect2, varscan2
- SLC35F1 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64499537; called by muse, mutect2, varscan2
- SLC39A12 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV66195710; called by muse, mutect2, varscan2
- SLC39A14 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 88/161 reads (55%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs763673454, COSV51482539; called by muse, mutect2, varscan2
- SMARCA4 | c.355+1G>T p.X119_splice | Splice Site (SNP) | VAF 20/29 reads (69%) | catalogued as COSV60788535; called by muse, mutect2, varscan2
- SMOC1 | c.500T>A p.L167* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV62759770; called by muse, mutect2, varscan2
- SNAPC4 | c.2175G>C p.Q725H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.459); catalogued as rs201265450; called by muse, mutect2
- SNTB1 | c.920A>T p.E307V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV67324841; called by muse, mutect2, varscan2
- SNTG2 | c.654C>A p.D218E | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57970413; called by muse, mutect2, varscan2
- SNX8 | c.1284+1G>A p.X428_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56125412; called by muse, mutect2
- SOX18 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV61110249; called by muse, mutect2, varscan2
- SPACA9 | c.389C>G p.A130G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53764383; called by muse, mutect2, varscan2
- SRRM2 | c.6254_6255insG p.D2086* | Frame Shift Ins (INS) | VAF 21/163 reads (13%) | catalogued as COSV99241239; called by mutect2, pindel, varscan2
- ST3GAL1 | c.936G>T p.K312N | Missense Mutation (SNP) | VAF 74/226 reads (33%) | PolyPhen benign (0.265); catalogued as COSV60610826; called by muse, mutect2, varscan2
- STAP2 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.847); catalogued as COSV74070971; called by muse, mutect2, varscan2
- STXBP5L | c.2788A>G p.R930G | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs772460530, COSV56502535; called by muse, mutect2, varscan2
- SUCO | c.1581A>G p.I527M | Missense Mutation (SNP) | VAF 104/252 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV55262672; called by muse, mutect2, varscan2
- SUCO | c.1802A>T p.Q601L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as COSV55262698; called by muse, mutect2, varscan2
- SUGP1 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV55920495, COSV99895225; called by muse, mutect2, varscan2
- SWT1 | c.1475G>C p.C492S | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62253213; called by muse, mutect2, varscan2
- SYNE1 | c.23929G>T p.D7977Y (on ENST00000367255 / NM_182961.4; = p.D7906Y on NM_033071.3) | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54921656; called by muse, mutect2, varscan2
- SYT4 | c.274T>A p.L92M | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54898672; called by muse, mutect2, varscan2
- SYTL2 | c.1778C>T p.P593L (on ENST00000528231 / NM_001162951.2; = p.P1882L on NM_206927.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as rs773149753, COSV60356424; called by muse, mutect2, varscan2
- SYTL3 | c.1034C>T p.P345L (on ENST00000611299 / NM_001242394.1; = p.P277L on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774253415, COSV51908430, COSV99791835; called by muse, mutect2, varscan2
- TAAR9 | c.690G>C p.K230N | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as COSV71512184; called by muse, mutect2, varscan2
- TAF3 | c.2670C>G p.Y890* | Nonsense Mutation (SNP) | VAF 22/194 reads (11%) | catalogued as COSV60203840; called by muse, mutect2, varscan2
- TAF5L | c.1021C>T p.H341Y | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51077671; called by muse, mutect2, varscan2
- TAS2R10 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV53700657; called by muse, mutect2, varscan2
- TBC1D16 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV60475888; called by muse, mutect2, varscan2
- TBX18 | c.790C>A p.H264N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63736223; called by muse, mutect2, varscan2
- TBX18 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63736226; called by muse, mutect2, varscan2
- TECPR2 | c.1466G>C p.C489S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.026); catalogued as COSV63969284; called by muse, mutect2, varscan2
- TFEB | c.866A>G p.Q289R | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57823811; called by muse, mutect2, varscan2
- TH | c.526C>T p.L176F (on ENST00000381178 / NM_199292.3; = p.L145F on NM_000360.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); catalogued as rs1180123781, COSV60766804; called by muse, mutect2, varscan2
- TMEM202 | c.653G>T p.R218I | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs771977232, COSV58981941; called by muse, mutect2, varscan2
- TMOD2 | c.884A>C p.Q295P | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs1271231919, COSV51042924; called by muse, mutect2, varscan2
- TMPRSS11E | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV59517760, COSV59518229; called by muse, mutect2, varscan2
- TNN | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53422524; called by muse, mutect2, varscan2
- TNN | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as rs200671106, COSV53420917; called by muse, mutect2, varscan2
- TNNT2 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52661246, COSV99372213; called by muse, mutect2, varscan2
- TNRC18 | c.8632G>A p.D2878N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51873075; called by muse, mutect2, varscan2
- TPD52L2 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV53861697; called by muse, mutect2, varscan2
- TRAPPC8 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as COSV51967922; called by muse, mutect2, varscan2
- TRIM55 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52544186; called by muse, mutect2, varscan2
- TRPM6 | c.1972G>T p.V658L | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV62503912; called by muse, mutect2, varscan2
- TRPV1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV51515800; called by muse, mutect2, varscan2
- TTF1 | c.998A>C p.K333T | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.056); catalogued as COSV57502548; called by muse, mutect2, varscan2
- TTN | c.90445C>A p.P30149T (on ENST00000591111; = p.P22725T on NM_003319.4) | Missense Mutation (SNP) | VAF 36/191 reads (19%) | PolyPhen possibly damaging (0.475); catalogued as COSV59914959; called by muse, mutect2, varscan2
- TTN | c.57566C>A p.S19189Y (on ENST00000591111; = p.S11765Y on NM_003319.4) | Missense Mutation (SNP) | VAF 36/195 reads (18%) | PolyPhen benign (0.179); catalogued as COSV59914977; called by muse, mutect2, varscan2
- UNC13B | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs773639167, COSV65931720; called by muse, mutect2, varscan2
- UNC5D | c.1900C>G p.H634D | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV54773765, COSV54793055; called by muse, mutect2, varscan2
- USB1 | c.699C>G p.I233M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV54682471; called by muse, mutect2, varscan2
- USP8 | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV56162751; called by muse, mutect2, varscan2
- UST | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV66545869, COSV66545917; called by muse, mutect2, varscan2
- VCAN | c.936G>T p.R312S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54098515, COSV54107023; called by muse, mutect2, varscan2
- VNN1 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV63389418; called by muse, mutect2, varscan2
- VPS13B | c.5558G>T p.C1853F | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.347); catalogued as COSV62134911, COSV62137882; called by muse, mutect2, varscan2
- VPS35 | c.1694A>G p.H565R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.159); catalogued as COSV54477344; called by muse, mutect2, varscan2
- WDR17 | c.2413A>G p.K805E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs756947891, COSV54569428; called by muse, mutect2, varscan2
- WDR64 | c.1319T>C p.L440S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63793168; called by muse, mutect2, varscan2
- WWP1 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV55356891; called by muse, mutect2, varscan2
- ZBTB17 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs1336395156, COSV65268472; called by muse, mutect2, varscan2
- ZBTB20 | c.974G>C p.G325A (on ENST00000474710 / NM_001164342.2; = p.G252A on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61844109, COSV61872813; called by muse, mutect2, varscan2
- ZDBF2 | c.5470C>T p.P1824S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.976); catalogued as COSV65622660; called by muse, mutect2
- ZFHX3 | c.7228A>G p.T2410A | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV51710767, COSV51720737; called by muse, mutect2, varscan2
- ZFHX4 | c.8423C>A p.T2808K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50551645; called by muse, mutect2, varscan2
- ZNF148 | c.676C>G p.P226A | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62302579; called by muse, mutect2, varscan2
- ZNF215 | c.1069T>A p.Y357N | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV53491943; called by muse, mutect2, varscan2
- ZNF492 | c.6A>C p.L2F | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71761730; called by muse, mutect2, varscan2
- ZNF677 | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100448162, COSV61719508; called by muse, mutect2, varscan2
- ZNF678 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.111); catalogued as rs1558158212, COSV59380570; called by muse, mutect2, varscan2
- ZNF70 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV59532260; called by muse, mutect2, varscan2
- ZNF804B | c.2553C>A p.H851Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV60818637; called by muse, mutect2, varscan2
- ABHD18 | c.543_544del p.L182Afs*32 (on ENST00000398965 / NM_001039717.2; = p.L55Afs*32 on NM_025097.2 and 10 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/41 reads (49%) | called by pindel, varscan2
- C8orf34 | c.850del p.L284* | Frame Shift Del (DEL) | VAF 14/117 reads (12%) | called by mutect2, pindel, varscan2
- DNAH9 | c.1100dup p.N367Kfs*9 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- DRD3 | c.428del p.G143Dfs*11 | Frame Shift Del (DEL) | VAF 29/110 reads (26%) | called by mutect2, pindel, varscan2
- GPR156 | c.1704dup p.S569Lfs*27 | Frame Shift Ins (INS) | VAF 19/170 reads (11%) | called by mutect2, pindel, varscan2
- HEATR9 | c.1117C>A p.L373M | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IGKV2D-30 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- MUC2 | c.1244A>G p.Y415C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NPNT | c.1552del p.H518Mfs*34 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- OR9G4 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- PGM2 | c.1600del p.A534Lfs*11 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel
- PSG9 | c.791_792insG p.K265* | Frame Shift Ins (INS) | VAF 130/345 reads (38%) | called by mutect2, pindel, varscan2
- RIMBP2 | c.2280_2282del p.D760del | In Frame Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- SLC12A9 | c.1488dup p.G497Rfs*4 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- SNRNP200 | c.6318_6319del p.Y2107Lfs*4 | Frame Shift Del (DEL) | VAF 15/131 reads (11%) | called by mutect2, pindel, varscan2
- SPZ1 | c.543_552del p.E182Tfs*8 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by pindel, varscan2
- TMEM59 | c.529dup p.I177Nfs*7 | Frame Shift Ins (INS) | VAF 8/84 reads (10%) | called by mutect2, pindel
- TUBGCP5 | c.2713A>G p.I905V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- AHNAK2 | c.1302C>A p.A434= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV60909250; called by muse, mutect2, varscan2
- ALX4 | c.1026G>C p.G342= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV61325148; called by muse, mutect2, varscan2
- ANK1 | c.96G>C p.R32= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV55875027; called by muse, mutect2, varscan2
- ARNTL2 | c.1827C>G p.A609= | Silent (SNP) | VAF 59/165 reads (36%) | catalogued as COSV53824055; called by muse, mutect2, varscan2
- ATP10D | c.2958T>G p.P986= | Silent (SNP) | VAF 61/104 reads (59%) | catalogued as COSV56704612; called by muse, mutect2, varscan2
- ATP12A | c.2964C>A p.L988= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV54512929, COSV54513193; called by muse, mutect2, varscan2
- BIRC6 | c.8928G>A p.S2976= | Silent (SNP) | VAF 65/196 reads (33%) | catalogued as rs747682260, COSV70196196; called by muse, mutect2, varscan2
- BTAF1 | c.4002G>A p.P1334= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs757434809, COSV56429485; called by muse, mutect2, varscan2
- CASR | c.528C>T p.N176= | Silent (SNP) | VAF 35/248 reads (14%) | catalogued as rs762352492, COSV56134839; called by muse, mutect2, varscan2
- CCDC114 | c.774C>G p.T258= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV59555606; called by muse, mutect2, varscan2
- CHGB | c.2031C>G p.G677= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV66759704; called by muse, mutect2, varscan2
- CHRNG | c.1408C>A p.R470= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as CM062515, COSV51471239; called by muse, mutect2, varscan2
- CMTM3 | c.423C>A p.I141= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs758402246, COSV58062273; called by muse, mutect2, varscan2
- CNTNAP2 | c.2418A>T p.P806= | Silent (SNP) | VAF 40/198 reads (20%) | catalogued as COSV62150648; called by muse, mutect2, varscan2
- CNTNAP5 | c.1164G>A p.G388= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs1159883207, COSV70469875, COSV70475480; called by muse, mutect2, varscan2
- CS | c.1074C>A p.T358= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as COSV57524000; called by muse, mutect2, varscan2
- CSAD | c.1119C>T p.G373= (on ENST00000444623 / NM_001244705.2; = p.G400= on NM_015989.5) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1016029539, COSV57241577; called by muse, mutect2, varscan2
- CTNNA2 | c.1023G>C p.A341= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV63550341, COSV63607520; called by muse, mutect2, varscan2
- CTNNA2 | c.1554G>A p.L518= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs942928904, COSV58138234, COSV58156326; called by muse, mutect2, varscan2
- DCSTAMP | c.357A>G p.K119= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs1271745180, COSV52576513; called by muse, mutect2, varscan2
- DISP3 | c.2880C>A p.S960= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV53821816; called by muse, mutect2, varscan2
- DNAH5 | c.4107C>T p.I1369= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV54208113; called by muse, mutect2
- EPB41L2 | c.1452A>G p.L484= | Silent (SNP) | VAF 60/223 reads (27%) | catalogued as rs758585681, COSV61353673; called by muse, mutect2, varscan2
- EPHB1 | c.2568C>A p.L856= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV67655199; called by muse, mutect2, varscan2
- FAT1 | c.6087A>G p.S2029= | Silent (SNP) | VAF 73/280 reads (26%) | catalogued as COSV71672312; called by muse, mutect2, varscan2
- FCRL6 | c.840C>T p.N280= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV58940162; called by muse, mutect2, varscan2
- FNDC11 | c.585C>A p.T195= | Silent (SNP) | VAF 130/191 reads (68%) | catalogued as rs73598377, COSV64442528; called by muse, mutect2, varscan2
- FXYD4 | c.48C>A p.A16= | Silent (SNP) | VAF 65/206 reads (32%) | catalogued as COSV72052642; called by muse, mutect2, varscan2
- GABRB3 | c.471G>C p.T157= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as COSV54652734, COSV54685176; called by muse, mutect2, varscan2
- GDA | c.1242G>T p.G414= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as COSV52990824; called by muse, mutect2, varscan2
- H3C4 | c.288C>A p.A96= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as COSV61911616; called by muse, mutect2
- IL1RAPL1 | c.1500T>A p.L500= | Silent (SNP) | VAF 44/66 reads (67%) | catalogued as COSV56241751; called by muse, mutect2, varscan2
- IL34 | c.99G>A p.E33= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV55380172; called by muse, mutect2, varscan2
- KLF5 | c.375T>G p.T125= | Silent (SNP) | VAF 47/223 reads (21%) | catalogued as COSV66613766; called by muse, mutect2, varscan2
- KLK1 | c.741G>A p.V247= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV56826109; called by muse, mutect2, varscan2
- LDB2 | c.345C>G p.S115= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV58763679; called by muse, mutect2, varscan2
- LRRN3 | c.948T>C p.A316= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV57817867; called by muse, mutect2, varscan2
- MAP10 | c.1146A>G p.P382= | Silent (SNP) | VAF 103/272 reads (38%) | catalogued as rs1410218311, COSV69362926; called by muse, mutect2, varscan2
- MED15 | c.2022C>T p.I674= (on ENST00000263205 / NM_001003891.3; = p.I634= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV53027208; called by muse, mutect2, varscan2
- MINDY3 | c.225G>T p.R75= | Silent (SNP) | VAF 67/251 reads (27%) | catalogued as COSV53218557; called by muse, mutect2, varscan2
- MYH6 | c.2175C>T p.R725= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs768890448, COSV62448300; called by muse, mutect2, varscan2
- NCOR2 | c.2881C>T p.L961= | Silent (SNP) | VAF 8/149 reads (5%) | catalogued as COSV62294161; called by muse, mutect2
- NOS1 | c.4006C>T p.L1336= | Silent (SNP) | VAF 66/133 reads (50%) | catalogued as COSV57607932, COSV57613637; called by muse, mutect2, varscan2
- OR51A4 | c.747G>C p.V249= | Silent (SNP) | VAF 48/186 reads (26%) | catalogued as COSV66749149; called by muse, mutect2, varscan2
- PCDH11Y | c.3780C>T p.L1260= | Silent (SNP) | VAF 72/194 reads (37%) | catalogued as COSV53075672; called by muse, mutect2, varscan2
- PCLO | c.6336A>T p.S2112= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV61619432; called by muse, mutect2, varscan2
- PDILT | c.1549C>T p.L517= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as COSV56699995; called by muse, mutect2, varscan2
- PGM2L1 | c.1281A>G p.K427= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as COSV53345508; called by muse, mutect2, varscan2
- PHF10 | c.834A>T p.P278= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV59321260; called by muse, mutect2, varscan2
- PHLPP2 | c.798G>A p.E266= | Silent (SNP) | VAF 64/159 reads (40%) | catalogued as COSV62422969; called by muse, mutect2, varscan2
- PLCH1 | c.1566G>T p.T522= (on ENST00000340059 / NM_001130960.2; = p.T534= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as rs200928567, COSV58189067, COSV58190949; called by muse, mutect2, varscan2
- PLD4 | c.975G>A p.L325= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV66914829; called by muse, mutect2, varscan2
- PRELP | c.1002C>T p.N334= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as rs1485133332, COSV58115108; called by muse, mutect2, varscan2
- PRPS1 | c.540C>T p.S180= | Silent (SNP) | VAF 74/204 reads (36%) | catalogued as COSV65054180; called by muse, mutect2, varscan2
- RAB33B | c.267A>T p.T89= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV59777138; called by muse, mutect2, varscan2
- RAD54B | c.903A>G p.K301= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs778616320, COSV60249901; called by muse, mutect2, varscan2
- RANBP17 | c.3240A>G p.E1080= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV66645320; called by muse, mutect2, varscan2
- RELN | c.2850G>A p.L950= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV58988694, COSV59028641; called by muse, mutect2, varscan2
- RIBC1 | c.243G>A p.E81= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV51447560; called by muse, mutect2, varscan2
- RSBN1 | c.2031C>T p.F677= | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as COSV54731326; called by muse, mutect2, varscan2
- SIGLEC12 | c.315C>T p.T105= | Silent (SNP) | VAF 68/170 reads (40%) | catalogued as COSV52459873; called by muse, mutect2, varscan2
- SLC26A4 | c.1140T>C p.D380= | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as COSV55914759; called by muse, mutect2, varscan2
- SLC4A3 | c.2460G>A p.S820= | Silent (SNP) | VAF 77/221 reads (35%) | catalogued as rs748156605, COSV56091997; called by muse, mutect2, varscan2
- SLCO1B1 | c.351C>T p.F117= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs1414521726, COSV57007918, COSV99918183; called by muse, mutect2, varscan2
- SMG1 | c.1164C>T p.V388= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV67169762; called by muse, mutect2, varscan2
- SPTA1 | c.75G>A p.Q25= | Silent (SNP) | VAF 43/212 reads (20%) | catalogued as COSV63749771, COSV63751714; called by muse, mutect2, varscan2
- TBX19 | c.240G>T p.G80= | Silent (SNP) | VAF 55/231 reads (24%) | catalogued as COSV63196883; called by muse, mutect2, varscan2
- TGS1 | c.474T>C p.S158= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV52698612; called by muse, mutect2, varscan2
- TNFSF13B | c.657C>G p.V219= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV65515816; called by muse, mutect2, varscan2
- TNXB | c.6516C>G p.V2172= (on ENST00000647633; = p.V1925= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/177 reads (8%) | catalogued as COSV64474657; called by muse, mutect2
- TSHR | c.1584C>A p.R528= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV53315377; called by muse, mutect2, varscan2
- TTN | c.3945T>A p.S1315= (on ENST00000591111; = p.S1269= on NM_003319.4) | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV59914999; called by muse, mutect2, varscan2
- YLPM1 | c.4884A>T p.P1628= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV53107255; called by mutect2, varscan2
- ZAN | c.2223C>A p.P741= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV61805844, COSV61811895; called by muse, mutect2, varscan2
- ZFPM2 | c.2092C>A p.R698= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs375403029, COSV101022963; called by mutect2, varscan2
- ZNF624 | c.522G>A p.R174= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as COSV60939332; called by muse, mutect2, varscan2
- ZNF648 | c.1038C>T p.R346= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV60569920; called by muse, varscan2
- A1CF | c.100-6638C>T | Intron (SNP) | VAF 57/238 reads (24%) | catalogued as COSV99255217; called by muse, mutect2, varscan2
- ARMC8 | c.45+931G>A | Intron (SNP) | VAF 40/152 reads (26%) | catalogued as COSV61767760; called by muse, mutect2, varscan2
- BACE2 | c.312+10896G>C | Intron (SNP) | VAF 11/26 reads (42%) | catalogued as rs1248326613, COSV57737814; called by muse, mutect2, varscan2
- BTN2A3P | n.183G>T | RNA (SNP) | VAF 38/114 reads (33%) | called by muse, mutect2, varscan2
- COL9A1 | c.781-68G>A | Intron (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100294017; called by muse, mutect2, varscan2
- DNAH8 | c.-149C>T | 5'UTR (SNP) | VAF 60/214 reads (28%) | catalogued as COSV59489928; called by muse, mutect2, varscan2
- DNM1L | c.251-1509C>G | Intron (SNP) | VAF 112/381 reads (29%) | catalogued as COSV99845752; called by muse, mutect2, varscan2
- HNRNPK | c.1362-51G>A | Intron (SNP) | VAF 53/109 reads (49%) | catalogued as COSV61088169; called by muse, mutect2, varscan2
- IPO7 | c.1425+191T>G | Intron (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100797795; called by muse, mutect2, varscan2
- MAP4K4 | c.1867-908A>C | Intron (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100153402; called by muse, mutect2, varscan2
- SLC25A3 | c.645-255G>T | Intron (SNP) | VAF 36/123 reads (29%) | catalogued as COSV99498960; called by muse, mutect2, varscan2
- ZNF107 | c.-1G>A | 5'UTR (SNP) | VAF 26/120 reads (22%) | catalogued as COSV100788214; called by muse, mutect2, varscan2
